Gene-level copy-number profile of tumor specimen TCGA-CN-6021-01A from TCGA case TCGA-CN-6021, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; Tumor grade: G2; Age at diagnosis: 63.6 years (23,212 days).
Specimen TCGA-CN-6021-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.e1d223e1-c959-4aa8-8549-0759130442bd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CN-6021-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c5e4b8d9-d2e7-4548-bf7d-fa097e2a20b5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 13,994; copy number 2: 39,051; copy number 3: 4,224; copy number 4: 637; copy number 5: 1,800; copy number 7: 108.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CN-6021-01A-11D-1682-01): tumor purity 0.43, ploidy 3.61, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,908 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:93,843,764–198,222,513, 1,800 genes, copy number 5 (broad region; genes not listed).
- chr14:34,659,564–40,390,547, 108 genes, copy number 7 (within-gene range 2–12) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 13,624. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
